Somatic mutation profile of tumor specimen HCM-CSHL-0250-C50-01A (aliquot HCM-CSHL-0250-C50-01A-11D-A82H-36) from HCMI case HCM-CSHL-0250-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.3 years (22,028 days).
Specimen HCM-CSHL-0250-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40f2355c-c217-476c-bd00-200491963b21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0250-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0250-C50-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de02efc4-ed1b-44ae-8dfb-c8543104a0de

The open-access MAF lists 36 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Frame Shift Ins 4, Nonsense Mutation 2, In Frame Del 2, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 151/436 reads (35%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- ASXL3 | c.5851T>C p.S1951P | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1414083031; called by muse, mutect2, varscan2
- DDX25 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1431146048; called by muse, mutect2, varscan2
- DRD2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 61/450 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV60757879; called by muse, mutect2, varscan2
- H1-1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs200599379; called by muse, mutect2
- KLHDC8A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 137/630 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs371072469; called by muse, mutect2, varscan2
- PGLYRP3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 127/874 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs763623473; called by muse, mutect2, varscan2
- PLA2G4D | c.1792C>T p.L598F | Missense Mutation (SNP) | VAF 140/781 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs765087738, COSV99299677; called by muse, mutect2
- PRDM15 | c.3178C>G p.P1060A | Missense Mutation (SNP) | VAF 147/444 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.656); catalogued as COSV54157530; called by muse, mutect2, varscan2
- SRD5A1 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 132/1026 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs776185174; called by mutect2, varscan2
- TMEM131 | c.4220A>C p.K1407T | Missense Mutation (SNP) | VAF 50/628 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as rs761938695; called by muse, mutect2
- UNC45B | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 81/456 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as rs1354715000, COSV52096263; called by muse, mutect2, varscan2
- ZNF831 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 159/639 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as rs200422985; called by muse, mutect2, varscan2
- CHTF18 | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 168/696 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- CLINT1 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 34/766 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- CUX1 | c.2902G>T p.E968* | Nonsense Mutation (SNP) | VAF 54/199 reads (27%) | called by muse, mutect2, varscan2
- ERBB2 | c.2092_2094del p.E698del | In Frame Del (DEL) | VAF 71/432 reads (16%) | called by mutect2, pindel, varscan2
- FASN | c.1641_1643del p.D548del | In Frame Del (DEL) | VAF 66/390 reads (17%) | called by pindel, varscan2
- GNAT3 | c.1051T>G p.C351G | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN2C | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 129/669 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- HSPA5 | c.1461_1462dup p.P488Lfs*17 | Frame Shift Ins (INS) | VAF 73/401 reads (18%) | called by mutect2, pindel, varscan2
- KDM6A | c.3284dup p.W1096Vfs*7 | Frame Shift Ins (INS) | VAF 16/178 reads (9%) | called by mutect2, pindel
- KLF13 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 26/909 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- MAGEB5 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 147/484 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUNX1 | c.293del p.P98Qfs*8 (on ENST00000344691 / NM_001001890.3; = p.P125Qfs*8 on NM_001754.5) | Frame Shift Del (DEL) | VAF 65/412 reads (16%) | called by mutect2, pindel, varscan2
- SERPINB9 | c.54dup p.L19Tfs*5 | Frame Shift Ins (INS) | VAF 64/337 reads (19%) | called by mutect2, pindel, varscan2
- STAT3 | c.1438_1441dup p.N481Ifs*69 | Frame Shift Ins (INS) | VAF 48/339 reads (14%) | called by mutect2, pindel, varscan2
- TEX47 | c.578_580dup p.T193dup | In Frame Ins (INS) | VAF 54/484 reads (11%) | called by mutect2, pindel
- TMEM200A | c.1356G>T p.K452N | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- UQCRH | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZCCHC3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 212/683 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- FGF23 | c.705C>T p.H235= | Silent (SNP) | VAF 35/890 reads (4%) | catalogued as rs1183278014, COSV52977546; called by muse, mutect2
- FMO2 | c.1104C>T p.C368= | Silent (SNP) | VAF 98/566 reads (17%) | catalogued as rs568414940; called by muse, mutect2, varscan2
- FOXK1 | c.480G>C p.L160= | Silent (SNP) | VAF 31/696 reads (4%) | catalogued as rs760256909; called by muse, mutect2
- KCNG4 | c.405G>T p.L135= | Silent (SNP) | VAF 80/514 reads (16%) | called by mutect2, varscan2
- STAB2 | c.2922G>A p.S974= | Silent (SNP) | VAF 35/309 reads (11%) | catalogued as rs150100761; called by muse, mutect2, varscan2
